Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A818, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A818-01A (Primary Tumor).

Left adrenalectomy

Date receiving:

Clinical history

Left pheochromocytoma

Histology

The piece of adrenalectomy weights 59g after dissection of adipose tissue. There is an adrenal tumor completely encapsulated measuring 5.5x4.5x4.5 cm with some hemorrhagic areas. Absence of mitosis. No necrosis, but there is a large fibrous star scar. Well capsulated. Absence of vascular invasion.

Samples taken in the normal adrenal cortex show a normal homogeneous adrenal cortex without nodulation.

CONCLUSION

Left adrenal paraganglioma or pheochromocytoma

PASS score = 1

Translated on from the original pathological report evaluated on

ICD-O.3
Pheochromocytoma NOS
8700/0
Site: Adrenal gland NOS
C74.9
JAW 10/17/13

Source: NCI Genomic Data Commons file a9d473db-9dc7-483f-8c86-32faf6f18826 (TCGA-WB-A818.5D7EFF64-D9CC-4474-9F92-E83672544ADF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).